Somatic mutation profile of tumor specimen ALCH-B3G3-TTP1-A (aliquot ALCH-B3G3-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3G3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 73.7 years (26,921 days).
Specimen ALCH-B3G3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cbe6967-349f-4ef3-b6bf-a3809a0e14b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3G3-NB1-A (Blood Derived Normal), aliquot ALCH-B3G3-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6dfa22c-adc1-4176-b15a-048df1bb8111

The open-access MAF lists 566 somatic variants for this specimen: 387 protein-altering or splice-affecting, 117 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 325, Silent 117, Nonsense Mutation 45, Intron 29, 5'UTR 11, Splice Site 9, 3'UTR 9, Splice Region 7, RNA 6, 3'Flank 4, 5'Flank 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 45/678 reads (7%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV52517787, COSV52518375; called by muse, mutect2
- TP53 | c.726C>A p.C242* | Nonsense Mutation (SNP) | VAF 103/797 reads (13%) | hotspot (GDC flag); catalogued as CM102354, COSV52677195, COSV52704436, COSV53034631; called by muse, mutect2, varscan2
- A1BG | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.104); catalogued as COSV54053398; called by muse, mutect2, varscan2
- ACHE | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 14/245 reads (6%) | catalogued as COSV53822086; called by muse, mutect2
- ACP6 | c.1250C>G p.S417C | Missense Mutation (SNP) | VAF 50/464 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs371044318; called by muse, mutect2, varscan2
- ADAD1 | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 40/478 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs912289238; called by muse, mutect2
- ADAM30 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs1199846716, COSV65560523; called by muse, mutect2
- ADCY5 | c.3444C>G p.I1148M | Missense Mutation (SNP) | VAF 35/1038 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV59205376; called by muse, mutect2
- ADGRG4 | c.5725A>G p.T1909A | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99796591; called by muse, mutect2, varscan2
- ADGRG6 | c.3263G>C p.W1088S | Missense Mutation (SNP) | VAF 24/391 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488577022; called by muse, mutect2
- ADPRH | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 56/548 reads (10%) | catalogued as rs779067913; called by muse, mutect2, varscan2
- AJUBA | c.1286G>T p.C429F | Missense Mutation (SNP) | VAF 38/531 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387232699; called by muse, mutect2
- ANKRD12 | c.5197C>G p.Q1733E | Missense Mutation (SNP) | VAF 21/531 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs1205053369; called by muse, mutect2
- ANKRD36 | c.636A>G p.I212M | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV101347571; called by muse, mutect2
- APP | c.2171A>G p.K724R | Missense Mutation (SNP) | VAF 26/860 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as CM149016; called by muse, mutect2
- ASXL3 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 22/624 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as rs1019750234; called by muse, mutect2
- ATXN7 | c.179C>G p.P60R | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.578); catalogued as rs755508121; called by muse, mutect2, varscan2
- B3GLCT | c.1364C>G p.S455C | Missense Mutation (SNP) | VAF 54/963 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58458334; called by muse, mutect2
- BBS9 | c.2632G>T p.E878* (on ENST00000242067 / NM_001348036.1; = p.E838* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 66/616 reads (11%) | catalogued as rs150826095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP7 | c.261C>A p.Y87* | Nonsense Mutation (SNP) | VAF 17/310 reads (5%) | catalogued as COSV67781990; called by muse, mutect2
- CAGE1 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 9/210 reads (4%) | catalogued as COSV99699636; called by muse, mutect2
- CCDC168 | c.4844C>A p.S1615* | Nonsense Mutation (SNP) | VAF 10/255 reads (4%) | catalogued as COSV70556127; called by muse, mutect2
- CDKL2 | c.1421C>A p.S474* | Nonsense Mutation (SNP) | VAF 27/279 reads (10%) | catalogued as COSV104409330, COSV56731798; called by muse, mutect2, varscan2
- COL22A1 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 49/408 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV57359411; called by muse, mutect2, varscan2
- COQ3 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 36/516 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54642516; called by muse, mutect2
- CPO | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 42/714 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55939556; called by muse, mutect2
- CRP | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 48/781 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54813322; called by muse, mutect2
- CTH | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 52/950 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100697127; called by muse, mutect2
- CTSG | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 32/919 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV53534900; called by muse, mutect2
- CYLC2 | c.661A>G p.K221E | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776451362; called by muse, mutect2
- CYP2C18 | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 18/431 reads (4%) | catalogued as COSV53672618; called by muse, mutect2
- DCLK3 | c.1033A>G p.M345V | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs751948204; called by muse, mutect2, varscan2
- DNAH9 | c.4123G>A p.E1375K | Missense Mutation (SNP) | VAF 55/376 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV52338279; called by muse, mutect2, varscan2
- DOCK2 | c.3186G>A p.M1062I | Missense Mutation (SNP) | VAF 21/527 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV56942133; called by muse, mutect2
- DOCK7 | c.2113G>T p.V705F | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360070798; called by muse, mutect2
- ELK3 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 29/352 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1157258409; called by muse, mutect2
- ELMO1 | c.86C>A p.P29Q | Missense Mutation (SNP) | VAF 46/466 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60317122; called by muse, mutect2
- FAM47B | c.203C>A p.T68K | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.356); catalogued as COSV61454332, COSV61455302; called by muse, mutect2, varscan2
- FANCE | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 110/1585 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV57691106; called by muse, mutect2
- FCRL2 | c.461C>A p.S154* | Nonsense Mutation (SNP) | VAF 92/908 reads (10%) | catalogued as COSV100829914; called by muse, mutect2, varscan2
- FLG | c.4081C>A p.H1361N | Missense Mutation (SNP) | VAF 164/1624 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.749); catalogued as rs780134687; called by muse, mutect2
- FOXP2 | c.1405G>A p.V469M | Missense Mutation (SNP) | VAF 20/534 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.298); catalogued as rs1230115579; called by muse, mutect2
- FUNDC2 | c.95C>A p.S32* | Nonsense Mutation (SNP) | VAF 13/169 reads (8%) | catalogued as COSV64270795; called by muse, mutect2
- GAA | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 48/578 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as rs201902338; ClinVar: uncertain significance; called by muse, mutect2
- GHR | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 19/546 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.079); catalogued as COSV50107957; called by muse, mutect2
- GOLGA6L2 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 25/716 reads (3%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.946); catalogued as rs1333793761; called by muse, mutect2
- GON4L | c.6311C>G p.S2104* | Nonsense Mutation (SNP) | VAF 21/439 reads (5%) | catalogued as COSV55204401; called by muse, mutect2
- GPATCH4 | c.1109G>A p.R370K | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100576891; called by muse, mutect2
- GPRC5B | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 19/425 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV56025053; called by muse, mutect2
- GRIN2B | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 17/433 reads (4%) | catalogued as rs1555133021, COSV74207843; called by muse, mutect2
- GRM5 | c.802T>A p.L268M | Missense Mutation (SNP) | VAF 88/1221 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59605070; called by muse, mutect2
- GSTA1 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 25/752 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV58017213; called by muse, mutect2
- GTF2F1 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV66727225; called by muse, mutect2
- HERC2 | c.8062C>G p.H2688D | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.966); catalogued as COSV55322246, COSV99877897; called by muse, mutect2
- HERPUD2 | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV60943973; called by muse, mutect2
- HES2 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 13/356 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222439654; called by muse, mutect2
- HMCN1 | c.7435C>T p.H2479Y | Missense Mutation (SNP) | VAF 35/907 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV54886984; called by muse, mutect2
- KPRP | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 34/355 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); catalogued as rs142207177; called by muse, mutect2
- LBX1-AS1 | n.422G>A | Splice Region (SNP) | VAF 40/679 reads (6%) | catalogued as rs1194966822; called by muse, mutect2
- LEMD2 | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 56/806 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV53395022; called by muse, mutect2
- LMTK2 | c.988A>G p.S330G | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as rs1194450514; called by muse, mutect2
- LTBR | c.424T>C p.C142R | Missense Mutation (SNP) | VAF 56/598 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1294894663; called by muse, mutect2
- MAGEA1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 46/446 reads (10%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.839); catalogued as COSV63119076; called by muse, mutect2, varscan2
- MED23 | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 60/494 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.529); catalogued as COSV63434542; called by muse, mutect2, varscan2
- MLIP | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 15/336 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.636); catalogued as COSV51429629; called by muse, mutect2
- MMP16 | c.1198G>C p.D400H | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54176946, COSV99688155; called by muse, mutect2, varscan2
- MNDA | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 35/551 reads (6%) | catalogued as rs145135870; called by muse, mutect2
- MORC2 | c.716C>T p.S239L (on ENST00000397641 / NM_001303256.3; = p.S177L on NM_014941.3) | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1387852860, COSV99309326; called by muse, mutect2, varscan2
- MROH2A | c.4739G>T p.R1580L | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV67680349; called by muse, mutect2
- MRPS12 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs772487012, COSV55498188; called by muse, mutect2, varscan2
- MUC16 | c.12476C>T p.S4159F | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs866038466; called by muse, mutect2
- MYO18B | c.4828G>C p.D1610H | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59151199; called by muse, mutect2, varscan2
- MYO1D | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 52/740 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.403); catalogued as COSV59017154; called by muse, mutect2
- NDUFS2 | c.203-3C>T | Splice Region (SNP) | VAF 42/722 reads (6%) | catalogued as rs755420872; called by muse, mutect2
- NKX6-3 | c.671C>T p.S224L (on ENST00000518699 / NM_001364841.2; = p.S94L on NM_152568.3) | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs1343600258, COSV101570831, COSV72895197; called by muse, mutect2
- NLGN1 | c.2396C>A p.T799K | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as rs1450055385; called by muse, mutect2
- NLGN4X | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52016108; called by muse, mutect2
- NLRP5 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 21/534 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs1289388301; called by muse, mutect2
- NPAS4 | c.2402C>T p.T801M | Missense Mutation (SNP) | VAF 18/361 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.201); catalogued as rs939601754; called by muse, mutect2
- NPHS1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV62288378; called by muse, mutect2
- NR5A1 | c.1180C>G p.Q394E | Missense Mutation (SNP) | VAF 18/552 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1057518497; ClinVar: uncertain significance; called by muse, mutect2
- P2RY14 | c.87C>G p.Y29* | Nonsense Mutation (SNP) | VAF 26/680 reads (4%) | catalogued as COSV56371433; called by muse, mutect2
- P4HB | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 49/473 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.36); catalogued as rs202116664; called by muse, mutect2, varscan2
- PCDHB6 | c.1295A>G p.Q432R | Missense Mutation (SNP) | VAF 60/994 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.107); catalogued as rs1554277724; called by muse, mutect2
- PCSK5 | c.2609G>A p.G870E | Missense Mutation (SNP) | VAF 34/353 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV65089911, COSV65093064; called by muse, mutect2
- PDE3A | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 29/358 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.041); catalogued as rs746694508, COSV100762198, COSV62981293; called by muse, mutect2
- PDZD11 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV52105500; called by muse, mutect2, varscan2
- PHC3 | c.298C>G p.Q100E (on ENST00000494943 / NM_001308116.2; = p.Q112E on NM_024947.4) | Missense Mutation (SNP) | VAF 25/582 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV71923709; called by muse, mutect2
- PLP1 | c.765C>T p.L255= | Splice Region (SNP) | VAF 32/482 reads (7%) | catalogued as COSV58278368; called by muse, mutect2
- PPP1R3A | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs762418405; called by muse, mutect2
- PRKCG | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 46/1123 reads (4%) | catalogued as COSV54726346; called by muse, mutect2
- PRKDC | c.10223G>T p.G3408V | Missense Mutation (SNP) | VAF 15/331 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs1016992202; called by muse, mutect2
- PRTN3 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 22/341 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.06); catalogued as rs1298181672; called by muse, mutect2
- PTCH1 | c.4034G>A p.R1345H | Missense Mutation (SNP) | VAF 51/624 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs766315655, COSV59467331; ClinVar: uncertain significance; called by muse, mutect2
- PTPN4 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 15/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1487806895, COSV55300972; called by muse, mutect2
- PTPRD | c.3542G>A p.R1181H | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs781067774, COSV61928613, COSV61938527, COSV61976608; called by muse, mutect2
- R3HDM1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 25/868 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51529322; called by muse, mutect2
- RALBP1 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 27/362 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV50039640; called by muse, mutect2
- RASA1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 32/1074 reads (3%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1187087405, CM1311699, COSV57191608, COSV57196650; called by muse, mutect2
- RCE1 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 40/620 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs916705255; called by muse, mutect2
- RGS4 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 94/1204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100905595, COSV63357266, COSV63357554; called by muse, mutect2
- RICTOR | c.3632C>G p.S1211* | Nonsense Mutation (SNP) | VAF 14/376 reads (4%) | catalogued as COSV57131048; called by muse, mutect2
- RNF25 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.301); catalogued as COSV55305759; called by muse, varscan2
- RUNX1T1 | c.1620G>C p.Q540H (on ENST00000265814 / NM_001198628.1; = p.Q513H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/897 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56150091; called by muse, mutect2
- RYR2 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100771991; called by muse, mutect2
- RYR2 | c.12759G>T p.L4253F | Missense Mutation (SNP) | VAF 120/1314 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as COSV63684386; called by muse, mutect2
- SCLT1 | c.1320G>T p.E440D | Missense Mutation (SNP) | VAF 23/377 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV99828692; called by muse, mutect2
- SLC17A4 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 49/473 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs776872293, COSV100930698; called by muse, mutect2, varscan2
- SLC37A1 | c.1272C>T p.A424= | Splice Region (SNP) | VAF 41/449 reads (9%) | catalogued as rs1180032372; called by muse, mutect2
- SLCO1B1 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 23/461 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57009440; called by muse, mutect2
- SMARCC1 | c.2072C>G p.S691* | Nonsense Mutation (SNP) | VAF 29/857 reads (3%) | catalogued as COSV54386292; called by muse, mutect2
- SORCS3 | c.2989C>T p.H997Y | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100863767, COSV63796584; called by muse, mutect2
- SOX13 | c.945G>T p.M315I | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99689823; called by muse, mutect2
- SPTA1 | c.5842G>A p.E1948K | Missense Mutation (SNP) | VAF 47/1081 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100934085, COSV63751122; called by muse, mutect2
- SSX5 | c.166G>A p.E56K (on ENST00000347757 / NM_175723.1; = p.E97K on NM_021015.4) | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as rs1439802689; called by muse, mutect2
- STAT5B | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 52/985 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV53181031; called by muse, mutect2
- SUZ12 | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.223); catalogued as rs901734535; called by muse, mutect2
- SYNE1 | c.3223G>A p.E1075K (on ENST00000367255 / NM_182961.4; = p.E1082K on NM_033071.3) | Missense Mutation (SNP) | VAF 52/499 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1436765500; called by muse, mutect2, varscan2
- TAS2R31 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 42/789 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs768032740; called by muse, mutect2
- TENM1 | c.6376C>T p.Q2126* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV64425882; called by muse, mutect2, varscan2
- TENM3 | c.3595C>T p.P1199S | Missense Mutation (SNP) | VAF 26/335 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1480797756, COSV101304936; called by muse, mutect2
- THSD7B | c.3067C>T p.R1023* | Nonsense Mutation (SNP) | VAF 32/473 reads (7%) | catalogued as rs750153977, COSV55661886; called by muse, mutect2
- TIMP3 | c.441C>G p.I147M | Missense Mutation (SNP) | VAF 58/1151 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV56667079; called by muse, mutect2
- TMEM200A | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.96); catalogued as rs768461562, COSV51649931; called by muse, mutect2
- TMEM71 | c.225G>C p.W75C | Missense Mutation (SNP) | VAF 80/1242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63460048; called by muse, mutect2
- TMTC1 | c.1161G>C p.L387F (on ENST00000539277 / NM_001193451.2; = p.L279F on NM_175861.3) | Missense Mutation (SNP) | VAF 18/519 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs1250731022, COSV55474430; called by muse, mutect2
- TNXB | c.12227G>C p.R4076P (on ENST00000647633; = p.R3829P on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/1114 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100926494; called by muse, mutect2
- TTN | c.5356G>T p.D1786Y (on ENST00000591111; = p.D1740Y on NM_003319.4) | Missense Mutation (SNP) | VAF 39/507 reads (8%) | PolyPhen probably damaging (0.999); catalogued as COSV60379406; called by muse, mutect2
- UBTF | c.1516-1G>T p.X506_splice | Splice Site (SNP) | VAF 23/422 reads (5%) | catalogued as COSV57186439; called by muse, mutect2
- UNC93A | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 100/1090 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs780488509, COSV100022902; called by muse, mutect2
- USP29 | c.1957G>C p.D653H | Missense Mutation (SNP) | VAF 27/437 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.092); catalogued as COSV99518581; called by muse, mutect2
- WDR72 | c.1558G>C p.E520Q | Missense Mutation (SNP) | VAF 19/487 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV64743179; called by muse, mutect2
- ZFP30 | c.828del p.K277Rfs*15 | Frame Shift Del (DEL) | VAF 42/360 reads (12%) | catalogued as COSV63622645; called by mutect2, varscan2
- ZFP37 | c.1190G>C p.R397T | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV65288828; called by muse, mutect2
- ZNF169 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 15/406 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs1564094133; called by muse, mutect2
- ZNF24 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 35/575 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV54348048; called by muse, mutect2
- ZNF275 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782074182; called by muse, mutect2
- ZNF365 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 32/599 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67925523; called by muse, mutect2
- ZNF536 | c.1434C>A p.H478Q | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV62819238; called by muse, mutect2, varscan2
- ZNF543 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 30/862 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as COSV58628433; called by muse, mutect2
- ACACA | c.5960G>T p.W1987L | Missense Mutation (SNP) | VAF 124/908 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ACKR3 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 30/542 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- ACSS3 | c.1315G>A p.V439I | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- ADAM12 | c.1866G>T p.L622F | Missense Mutation (SNP) | VAF 35/785 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS17 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 46/1102 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- ADCY9 | c.3973G>T p.G1325C | Missense Mutation (SNP) | VAF 34/483 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); called by muse, mutect2
- AKAP12 | c.2060C>T p.S687L | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- AKAP8L | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 39/386 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- ANKRD17 | c.6481C>G p.Q2161E | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.204); called by muse, mutect2
- ANKRD50 | c.1723G>T p.D575Y | Missense Mutation (SNP) | VAF 36/515 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AOAH | c.224-1G>C p.X75_splice | Splice Site (SNP) | VAF 19/302 reads (6%) | called by muse, mutect2
- ARHGAP17 | c.2519C>T p.S840F (on ENST00000289968 / NM_001006634.3; = p.S762F on NM_018054.6) | Missense Mutation (SNP) | VAF 12/303 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); called by muse, mutect2
- ARHGAP30 | c.154G>T p.G52W | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGAP30 | c.153T>A p.D51E | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ASTN1 | c.1976G>T p.G659V | Missense Mutation (SNP) | VAF 72/896 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATMIN | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 16/303 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.022); called by muse, mutect2
- ATP10D | c.2663T>A p.L888* | Nonsense Mutation (SNP) | VAF 17/253 reads (7%) | called by muse, mutect2
- ATP10D | c.3685G>T p.G1229* | Nonsense Mutation (SNP) | VAF 41/472 reads (9%) | called by muse, mutect2
- ATP10D | c.3686G>T p.G1229V | Missense Mutation (SNP) | VAF 41/482 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- ATP2B2 | c.2696T>A p.M899K (on ENST00000352432; = p.M865K on NM_001683.5) | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2
- ATRX | c.4199A>T p.Q1400L | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- AVPR1A | c.873G>C p.K291N | Missense Mutation (SNP) | VAF 30/640 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- BBOX1 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 42/564 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); called by muse, mutect2
- BIRC6 | c.4798G>T p.G1600W | Missense Mutation (SNP) | VAF 29/487 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BMX | c.1304A>C p.K435T | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- BOD1L1 | c.4390G>T p.G1464C | Missense Mutation (SNP) | VAF 31/396 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); called by muse, mutect2
- C19orf57 | c.1987C>T p.P663S (on ENST00000586783 / NM_001345843.1; = p.P632S on NM_024323.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/394 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CADPS | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CASQ2 | c.515A>G p.K172R | Missense Mutation (SNP) | VAF 32/918 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); called by muse, mutect2
- CCDC159 | c.4G>C p.G2R | Missense Mutation (SNP) | VAF 57/640 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CCNT1 | c.1627G>C p.G543R | Missense Mutation (SNP) | VAF 18/289 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2
- CDH8 | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 28/576 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.702); called by muse, mutect2
- CFAP65 | c.5218G>A p.D1740N | Missense Mutation (SNP) | VAF 26/494 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.035); called by muse, mutect2
- CHD6 | c.1775G>A p.W592* | Nonsense Mutation (SNP) | VAF 32/540 reads (6%) | called by muse, mutect2
- CKAP2 | c.144G>C p.E48D | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2
- CNTLN | c.2864G>T p.S955I | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- CNTNAP1 | c.2953T>G p.C985G | Missense Mutation (SNP) | VAF 25/318 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTNAP2 | c.2216C>G p.P739R | Missense Mutation (SNP) | VAF 33/806 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.317); called by muse, mutect2
- COBL | c.3689C>A p.T1230N | Missense Mutation (SNP) | VAF 24/565 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2
- COL14A1 | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 14/343 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- COL22A1 | c.3277G>T p.G1093C | Missense Mutation (SNP) | VAF 40/462 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL3A1 | c.2827G>T p.A943S | Missense Mutation (SNP) | VAF 36/796 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- COL6A1 | c.2620G>C p.A874P | Missense Mutation (SNP) | VAF 54/538 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2
- CPS1 | c.2833G>T p.D945Y | Missense Mutation (SNP) | VAF 50/866 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CRLF1 | c.833T>G p.V278G | Missense Mutation (SNP) | VAF 30/513 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- CTBP1 | c.1139G>T p.R380M | Missense Mutation (SNP) | VAF 39/654 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); called by muse, mutect2
- CYB5R4 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2
- DCTN2 | c.463G>C p.E155Q (on ENST00000548249 / NM_001261413.2; = p.E160Q on NM_006400.4) | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.321); called by muse, mutect2
- DDC | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 50/1178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX11 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 30/820 reads (4%) | called by muse, mutect2
- DEUP1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2
- DMPK | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 24/510 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- DMXL1 | c.3931C>G p.L1311V | Missense Mutation (SNP) | VAF 36/521 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAJC13 | c.6288G>T p.M2096I | Missense Mutation (SNP) | VAF 44/588 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- DPP9 | c.1306G>C p.E436Q (on ENST00000598800; = p.E465Q on NM_139159.5) | Missense Mutation (SNP) | VAF 26/526 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2
- DPY19L1 | c.685C>G p.H229D | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- DRD3 | c.298C>A p.R100S | Missense Mutation (SNP) | VAF 19/430 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- DTHD1 | c.1810G>A p.E604K (on ENST00000456874; = p.E439K on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/988 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); called by muse, mutect2
- EHBP1 | c.3430G>C p.D1144H | Missense Mutation (SNP) | VAF 32/464 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EIF4G1 | c.4615C>T p.P1539S (on ENST00000346169 / NM_198241.3; = p.P1344S on NM_004953.5) | Missense Mutation (SNP) | VAF 20/452 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.191); called by muse, mutect2
- EIPR1 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 46/732 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.11); called by muse, mutect2
- EQTN | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 53/612 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2
- FAM189B | c.1687G>A p.V563I | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FAM83B | c.2096C>A p.P699H | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAT4 | c.12175G>C p.G4059R | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FGD1 | c.829A>G p.K277E | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FIGN | c.976C>A p.Q326K | Missense Mutation (SNP) | VAF 29/746 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2
- FKBP6 | c.738G>C p.L246F | Missense Mutation (SNP) | VAF 32/1088 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FNDC1 | c.895G>T p.V299L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- FNDC7 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- FZD4 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.592); called by muse, mutect2
- GALNT1 | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 24/782 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GALNT7 | c.400A>G p.N134D | Missense Mutation (SNP) | VAF 26/424 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- GAPVD1 | c.1918G>A p.G640R | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- GDF10 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2, varscan2
- GLCCI1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 34/638 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GMNC | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GOLGA8J | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 36/1558 reads (2%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2
- GPC5 | c.203G>T p.C68F | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPC6 | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 42/632 reads (7%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.703); called by muse, mutect2
- GRIA1 | c.2377G>C p.D793H | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2
- H1-5 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 40/942 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- H2AJ | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 28/331 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2
- HAUS1 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 32/578 reads (6%) | called by muse, mutect2
- HBP1 | c.797C>G p.S266* | Nonsense Mutation (SNP) | VAF 14/350 reads (4%) | called by muse, mutect2
- HECW2 | c.4174G>T p.G1392C | Missense Mutation (SNP) | VAF 31/437 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HEXIM1 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 34/732 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- HYDIN | c.1871G>T p.R624I | Missense Mutation (SNP) | VAF 79/931 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- IFIH1 | c.851C>G p.S284* | Nonsense Mutation (SNP) | VAF 16/438 reads (4%) | called by muse, mutect2
- IGKV1D-16 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 92/1526 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2
- IGKV1D-8 | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 42/712 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2
- IGKV2D-29 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 30/752 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.144); called by muse, mutect2
- IGSF9B | c.1450G>T p.G484W | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IPO8 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 21/443 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2
- IRAK1 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.314); called by muse, mutect2
- KDM6A | c.444-3C>T | Splice Region (SNP) | VAF 20/260 reads (8%) | called by muse, mutect2
- KIF14 | c.2656G>A p.D886N | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, varscan2
- KIF21A | c.971G>C p.R324T | Missense Mutation (SNP) | VAF 15/387 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIR3DL2 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 72/905 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2
- KMT5B | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 18/311 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- KPNA1 | c.338-1G>A p.X113_splice | Splice Site (SNP) | VAF 22/418 reads (5%) | called by muse, mutect2
- KRTAP10-12 | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 68/1233 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- KSR1 | c.2781G>C p.K927N | Missense Mutation (SNP) | VAF 26/824 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- LARP6 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 15/307 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2
- LARS1 | c.3332C>T p.S1111F (on ENST00000394434 / NM_020117.11; = p.S1084F on NM_016460.3) | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2
- LAYN | c.248C>G p.S83C (on ENST00000375615 / NM_001258390.1; = p.S75C on NM_178834.5) | Missense Mutation (SNP) | VAF 26/800 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- LDB3 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 32/766 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- LINGO4 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0); called by mutect2, varscan2
- LNPK | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- LRP1B | c.9530T>C p.M3177T | Missense Mutation (SNP) | VAF 19/422 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- LRP2 | c.11969C>G p.S3990C | Missense Mutation (SNP) | VAF 42/600 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2
- LRPPRC | c.3537C>G p.F1179L | Missense Mutation (SNP) | VAF 29/852 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.314); called by muse, mutect2
- LSG1 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 17/268 reads (6%) | called by muse, mutect2
- LTBP1 | c.1324C>T p.L442F (on ENST00000404816 / NM_206943.4; = p.L116F on NM_000627.4) | Missense Mutation (SNP) | VAF 26/804 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.355); called by muse, mutect2
- LY6G6C | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 44/511 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2
- MAG | c.1113C>A p.Y371* | Nonsense Mutation (SNP) | VAF 106/815 reads (13%) | called by muse, mutect2, varscan2
- MALRD1 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 36/546 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP3K2 | c.1366A>T p.T456S | Missense Mutation (SNP) | VAF 39/517 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by muse, mutect2
- MCCC1 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 73/731 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCM3AP | c.1988G>A p.G663E | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2
- MDM4 | c.1411G>A p.G471R | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.97); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MED12 | c.5218G>C p.E1740Q | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- MIA3 | c.1858G>C p.E620Q | Missense Mutation (SNP) | VAF 38/379 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MKLN1 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 18/417 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- MRC1 | c.2323T>A p.W775R | Missense Mutation (SNP) | VAF 60/1054 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRRF | c.552-1G>T p.X184_splice | Splice Site (SNP) | VAF 22/642 reads (3%) | called by muse, mutect2
- MUC17 | c.4994C>G p.S1665C | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2
- MUC4 | c.10177C>G p.L3393V | Missense Mutation (SNP) | VAF 58/1794 reads (3%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.374); called by muse, mutect2
- MUC5B | c.2651G>A p.W884* | Nonsense Mutation (SNP) | VAF 22/140 reads (16%) | called by muse, varscan2
- MYLK2 | c.906C>G p.C302W | Missense Mutation (SNP) | VAF 76/978 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO1A | c.2500G>A p.D834N | Missense Mutation (SNP) | VAF 35/287 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- MYO5A | c.2208+1G>T p.X736_splice | Splice Site (SNP) | VAF 56/917 reads (6%) | called by muse, mutect2
- MYOM3 | c.1867G>T p.D623Y | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2
- NAT1 | c.529C>G p.H177D | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- NCOA2 | c.2203G>T p.V735L | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NDFIP1 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NEB | c.8015C>G p.S2672C | Missense Mutation (SNP) | VAF 28/603 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NEK11 | c.1176+2T>G p.X392_splice | Splice Site (SNP) | VAF 53/308 reads (17%) | called by muse, mutect2, varscan2
- NIN | c.5317G>C p.D1773H (on ENST00000382041 / NM_182946.1; = p.D1060H on NM_016350.4) | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NKTR | c.3100C>G p.Q1034E | Missense Mutation (SNP) | VAF 36/326 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 28/691 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- NPY2R | c.8C>A p.P3Q | Missense Mutation (SNP) | VAF 34/862 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.22); called by muse, mutect2
- NUP37 | c.855A>T p.L285F | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2
- OR10T2 | c.36G>T p.Q12H | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- OR3A3 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 98/630 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR51F1 | c.169G>T p.V57F | Missense Mutation (SNP) | VAF 29/331 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2
- OR52N4 | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 19/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- OR5B2 | c.410G>T p.S137I | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.385); called by muse, mutect2
- OR5H15 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 50/856 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.21); called by muse, mutect2
- OR6P1 | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 32/460 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by muse, mutect2
- PASK | c.2608C>T p.Q870* | Nonsense Mutation (SNP) | VAF 26/608 reads (4%) | called by muse, mutect2
- PCDH10 | c.1664C>A p.A555D | Missense Mutation (SNP) | VAF 44/776 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2
- PCDH17 | c.2432C>A p.S811* | Nonsense Mutation (SNP) | VAF 32/396 reads (8%) | called by muse, mutect2
- PCLO | c.5379G>T p.R1793S | Missense Mutation (SNP) | VAF 20/441 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2
- PDE3A | c.2986C>T p.Q996* | Nonsense Mutation (SNP) | VAF 70/818 reads (9%) | called by muse, mutect2
- PDE4A | c.23C>G p.S8W | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- PER3 | c.2279G>T p.R760L | Missense Mutation (SNP) | VAF 16/472 reads (3%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- PFAS | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- PHF12 | c.1919C>T p.T640I | Missense Mutation (SNP) | VAF 42/988 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.326); called by muse, mutect2
- PHLDB1 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 18/590 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PITRM1 | c.2235+2T>A p.X745_splice | Splice Site (SNP) | VAF 36/713 reads (5%) | called by muse, mutect2
- PLTP | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 72/1004 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.858); called by muse, mutect2
- PNLIPRP3 | c.570G>C p.L190F | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- POPDC2 | c.980G>T p.R327M | Missense Mutation (SNP) | VAF 63/696 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2
- POTEF | c.2534C>G p.S845C | Missense Mutation (SNP) | VAF 39/936 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- PPFIA2 | c.1690G>T p.D564Y | Missense Mutation (SNP) | VAF 30/734 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- PPIAL4D | c.356C>A p.T119N | Missense Mutation (SNP) | VAF 81/1712 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.672); called by muse, mutect2
- PRELID1 | c.419C>G p.S140C | Missense Mutation (SNP) | VAF 17/391 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.2); called by muse, mutect2
- PREX1 | c.3845C>A p.P1282H | Missense Mutation (SNP) | VAF 27/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PRRG1 | c.324C>A p.N108K | Missense Mutation (SNP) | VAF 79/445 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSKH2 | c.372G>T p.M124I | Missense Mutation (SNP) | VAF 24/858 reads (3%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- PTPRB | c.603A>G p.T201= | Splice Region (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- RAD9A | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- RANBP2 | c.9005C>G p.A3002G | Missense Mutation (SNP) | VAF 34/644 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2
- RASA2 | c.1769C>A p.S590* | Nonsense Mutation (SNP) | VAF 32/384 reads (8%) | called by muse, mutect2
- RASGEF1A | c.1309C>T p.Q437* | Nonsense Mutation (SNP) | VAF 28/572 reads (5%) | called by muse, mutect2
- REG3G | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.563); called by muse, mutect2
- RELN | c.10129C>A p.H3377N | Missense Mutation (SNP) | VAF 74/978 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- RELN | c.3455G>T p.G1152V | Missense Mutation (SNP) | VAF 46/974 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- RMDN2 | c.258G>C p.M86I | Missense Mutation (SNP) | VAF 25/365 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.052); called by muse, mutect2
- RMDN2 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 24/362 reads (7%) | called by muse, mutect2
- RNF111 | c.1855G>C p.D619H | Missense Mutation (SNP) | VAF 26/856 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- RPRD2 | c.4273G>A p.E1425K | Missense Mutation (SNP) | VAF 19/644 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- SALL2 | c.2809G>A p.G937R | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (1); called by muse, mutect2
- SCML2 | c.1915T>C p.F639L | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SEC31A | c.83C>A p.T28K | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SEMA5A | c.3194T>A p.F1065Y | Missense Mutation (SNP) | VAF 56/748 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.015); called by muse, mutect2
- SKAP1 | c.828T>C p.D276= | Splice Region (SNP) | VAF 32/411 reads (8%) | called by muse, mutect2
- SLC22A16 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 22/548 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, mutect2
- SLC22A2 | c.1462C>A p.L488I | Missense Mutation (SNP) | VAF 20/458 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC27A1 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 20/514 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SLC30A9 | c.508A>T p.R170* | Nonsense Mutation (SNP) | VAF 11/149 reads (7%) | called by muse, mutect2
- SLC36A1 | c.546C>A p.N182K | Missense Mutation (SNP) | VAF 37/400 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.009); called by muse, mutect2
- SLC5A3 | c.1606C>G p.P536A | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMARCA4 | c.3418A>T p.K1140* | Nonsense Mutation (SNP) | VAF 50/582 reads (9%) | called by muse, mutect2
- SMARCAD1 | c.2479G>T p.D827Y | Missense Mutation (SNP) | VAF 23/571 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMARCC2 | c.745A>C p.N249H | Missense Mutation (SNP) | VAF 26/626 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- SMO | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 25/473 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SPRN | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by mutect2, varscan2
- SPTA1 | c.4515C>G p.F1505L | Missense Mutation (SNP) | VAF 86/863 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPTA1 | c.480C>A p.F160L | Missense Mutation (SNP) | VAF 80/1004 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SRRM2 | c.7264G>A p.E2422K | Missense Mutation (SNP) | VAF 36/539 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- STARD9 | c.10526C>G p.A3509G | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- STYK1 | c.188-2A>T p.X63_splice | Splice Site (SNP) | VAF 16/165 reads (10%) | called by muse, mutect2, varscan2
- SUGT1 | c.1062C>G p.I354M (on ENST00000343788 / NM_001130912.3; = p.I322M on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.141); called by muse, mutect2
- SZT2 | c.8420-1G>C p.X2807_splice (on ENST00000634258 / NM_001365999.1; = p.X2750_splice on NM_015284.4) | Splice Site (SNP) | VAF 16/333 reads (5%) | called by muse, mutect2
- TAFA2 | c.239C>A p.A80D | Missense Mutation (SNP) | VAF 31/316 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TANGO6 | c.2701G>C p.G901R | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TAS1R2 | c.1024G>C p.G342R | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- TENM1 | c.7742T>C p.L2581P | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TENM4 | c.5980G>T p.E1994* | Nonsense Mutation (SNP) | VAF 81/369 reads (22%) | called by muse, mutect2, varscan2
- TFAP2C | c.843G>C p.K281N | Missense Mutation (SNP) | VAF 25/450 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2
- TLR1 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2
- TMEM132C | c.3234T>A p.N1078K | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.117); called by muse, mutect2
- TMEM72 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TMTC1 | c.1878A>C p.L626F (on ENST00000539277 / NM_001193451.2; = p.L518F on NM_175861.3) | Missense Mutation (SNP) | VAF 36/619 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TNK2 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 16/494 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2
- TNS1 | c.4870G>A p.E1624K | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2
- TP53BP1 | c.3911C>A p.S1304Y | Missense Mutation (SNP) | VAF 29/892 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2
- TRAM1L1 | c.738C>A p.Y246* | Nonsense Mutation (SNP) | VAF 23/297 reads (8%) | called by muse, mutect2
- TTK | c.2374C>G p.Q792E | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2
- TTLL2 | c.80T>A p.L27H | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.657); called by muse, mutect2
- TTN | c.84108C>A p.S28036R (on ENST00000591111; = p.S20612R on NM_003319.4) | Missense Mutation (SNP) | VAF 18/302 reads (6%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- UCKL1 | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 21/517 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.083); called by muse, mutect2
- UCP3 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- UFSP2 | c.167G>A p.C56Y | Missense Mutation (SNP) | VAF 24/667 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.172); called by muse, mutect2
- UNC79 | c.1096G>A p.E366K (on ENST00000393151 / NM_001346218.2; = p.E189K on NM_020818.5) | Missense Mutation (SNP) | VAF 18/371 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2
- WEE1 | c.632G>C p.S211T | Missense Mutation (SNP) | VAF 22/730 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2
- WNT10B | c.587G>T p.W196L | Missense Mutation (SNP) | VAF 36/515 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WWC2 | c.2218G>T p.V740F | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- XIRP2 | c.129G>T p.L43F | Missense Mutation (SNP) | VAF 42/542 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.667); called by muse, mutect2
- XIRP2 | c.5624A>T p.H1875L (on ENST00000628543; = p.H2050L on NM_152381.6) | Missense Mutation (SNP) | VAF 17/312 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2
- ZBED9 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 70/828 reads (8%) | called by muse, mutect2
- ZBTB38 | c.1465C>G p.P489A | Missense Mutation (SNP) | VAF 18/405 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZDHHC5 | c.968A>T p.Y323F | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2
- ZFAND4 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- ZNF16 | c.1645G>C p.E549Q | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF334 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 32/327 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- ZNF445 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 38/520 reads (7%) | called by muse, mutect2
- ZNF528 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 50/668 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF609 | c.3560C>G p.T1187R | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.159); called by muse, mutect2
- ZNF672 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF729 | c.1450G>T p.G484* | Nonsense Mutation (SNP) | VAF 74/1208 reads (6%) | called by muse, mutect2
- ZNF805 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 57/1007 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- ZNF836 | c.440C>G p.S147* | Nonsense Mutation (SNP) | VAF 18/159 reads (11%) | called by muse, mutect2, varscan2
- ZNF865 | c.2308G>C p.G770R | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); called by muse, mutect2
- ZNHIT6 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 20/395 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.468); called by muse, mutect2
- ACSM5 | c.708C>A p.A236= | Silent (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- ADAMTS7 | c.171C>T p.F57= | Silent (SNP) | VAF 31/841 reads (4%) | catalogued as COSV66309439; called by muse, mutect2
- AGTPBP1 | c.2796A>C p.G932= (on ENST00000357081 / NM_001330701.2; = p.G892= on NM_015239.2) | Silent (SNP) | VAF 44/552 reads (8%) | called by muse, mutect2
- ANAPC5 | c.1362G>A p.V454= | Silent (SNP) | VAF 19/507 reads (4%) | called by muse, mutect2
- ANK2 | c.5367C>A p.I1789= | Silent (SNP) | VAF 30/398 reads (8%) | called by muse, mutect2
- ANKDD1A | c.708C>T p.S236= | Silent (SNP) | VAF 34/478 reads (7%) | called by muse, mutect2
- AP001781.2 | c.60G>A p.L20= | Silent (SNP) | VAF 20/472 reads (4%) | catalogued as COSV52786279; called by muse, mutect2
- BBS7 | c.303C>G p.L101= | Silent (SNP) | VAF 24/394 reads (6%) | called by muse, mutect2
- BRD9 | c.354G>T p.V118= | Silent (SNP) | VAF 11/227 reads (5%) | called by muse, mutect2
- CACNG7 | c.708G>C p.A236= | Silent (SNP) | VAF 18/432 reads (4%) | catalogued as COSV55813930; called by muse, mutect2
- CATSPER2 | c.927G>T p.V309= | Silent (SNP) | VAF 64/912 reads (7%) | called by muse, mutect2
- CCDC110 | c.2166A>G p.L722= | Silent (SNP) | VAF 13/209 reads (6%) | called by muse, mutect2
- CCDC166 | c.981G>T p.P327= | Silent (SNP) | VAF 14/303 reads (5%) | called by muse, mutect2
- CCDC180 | c.3816A>T p.S1272= | Silent (SNP) | VAF 41/576 reads (7%) | called by muse, mutect2
- CDV3 | c.534A>T p.T178= | Silent (SNP) | VAF 43/442 reads (10%) | called by muse, mutect2, varscan2
- CELSR2 | c.2274C>T p.F758= | Silent (SNP) | VAF 13/278 reads (5%) | catalogued as COSV54768459; called by muse, mutect2
- CFAP54 | c.5034A>G p.P1678= | Silent (SNP) | VAF 41/512 reads (8%) | called by muse, mutect2
- CHIA | c.222G>A p.V74= | Silent (SNP) | VAF 27/559 reads (5%) | called by muse, mutect2
- COL4A6 | c.1110A>T p.P370= | Silent (SNP) | VAF 25/260 reads (10%) | catalogued as rs1172150592; called by muse, mutect2
- COL7A1 | c.5409G>A p.G1803= | Silent (SNP) | VAF 29/212 reads (14%) | catalogued as rs1435271519; called by muse, mutect2, varscan2
- COQ4 | c.6G>A p.A2= | Silent (SNP) | VAF 20/249 reads (8%) | called by muse, mutect2
- CRNKL1 | c.636G>A p.Q212= | Silent (SNP) | VAF 16/473 reads (3%) | called by muse, mutect2
- CYP4F12 | c.1035G>A p.A345= | Silent (SNP) | VAF 34/340 reads (10%) | catalogued as rs753117286; called by muse, mutect2
- DAPK1 | c.3024C>G p.L1008= | Silent (SNP) | VAF 18/414 reads (4%) | catalogued as COSV63791591; called by muse, mutect2
- DDX43 | c.846T>C p.L282= | Silent (SNP) | VAF 28/370 reads (8%) | called by muse, mutect2
- DDX6 | c.987C>T p.F329= | Silent (SNP) | VAF 12/261 reads (5%) | catalogued as COSV50587834; called by muse, mutect2
- DEF8 | c.948C>T p.I316= | Silent (SNP) | VAF 17/147 reads (12%) | catalogued as COSV51920808; called by muse, mutect2, varscan2
- DMBT1 | c.7572C>T p.V2524= (on ENST00000338354 / NM_001377530.1; = p.V1767= on NM_004406.3) | Silent (SNP) | VAF 27/370 reads (7%) | catalogued as COSV57534536; called by muse, mutect2
- DMRT2 | c.1584C>A p.A528= | Silent (SNP) | VAF 25/415 reads (6%) | called by muse, mutect2
- DNAH12 | c.5085G>A p.L1695= (on ENST00000351747; = p.L1718= on NM_001366028.2) | Silent (SNP) | VAF 9/201 reads (4%) | catalogued as COSV61059674; called by muse, mutect2
- DNAH2 | c.8709C>A p.I2903= | Silent (SNP) | VAF 44/289 reads (15%) | called by muse, mutect2, varscan2
- DPEP3 | c.1137G>T p.L379= | Silent (SNP) | VAF 36/365 reads (10%) | catalogued as COSV52052422; called by muse, mutect2
- DUSP22 | c.354G>A p.V118= | Silent (SNP) | VAF 66/1188 reads (6%) | called by muse, mutect2
- ECEL1 | c.246C>A p.L82= | Silent (SNP) | VAF 11/213 reads (5%) | called by muse, mutect2
- EIF2B4 | c.609C>T p.I203= (on ENST00000347454 / NM_001034116.2; = p.I202= on NM_015636.3) | Silent (SNP) | VAF 65/679 reads (10%) | catalogued as COSV52008885; called by muse, mutect2
- ENPEP | c.690T>A p.S230= | Silent (SNP) | VAF 16/323 reads (5%) | called by muse, mutect2
- FAM110C | c.864G>A p.E288= | Silent (SNP) | VAF 25/480 reads (5%) | catalogued as COSV59655714; called by muse, mutect2
- FAM170A | c.552C>T p.D184= | Silent (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- FAN1 | c.441G>C p.V147= | Silent (SNP) | VAF 17/413 reads (4%) | called by muse, mutect2
- FBXO10 | c.1158G>T p.G386= | Silent (SNP) | VAF 20/319 reads (6%) | called by muse, mutect2
- FLNA | c.7071G>T p.L2357= (on ENST00000369850 / NM_001110556.2; = p.L2349= on NM_001456.3) | Silent (SNP) | VAF 30/434 reads (7%) | called by muse, mutect2
- FN1 | c.7014T>C p.G2338= (on ENST00000359671 / NM_001365524.2; = p.G2307= on NM_002026.4) | Silent (SNP) | VAF 37/506 reads (7%) | called by muse, mutect2
- GATA1 | c.892C>A p.R298= | Silent (SNP) | VAF 88/550 reads (16%) | catalogued as rs1060501251; called by muse, varscan2
- GHRHR | c.1068C>T p.I356= | Silent (SNP) | VAF 74/615 reads (12%) | catalogued as COSV58198384; called by muse, mutect2, varscan2
- GRAP2 | c.630G>T p.A210= | Silent (SNP) | VAF 41/328 reads (13%) | catalogued as COSV59997152; called by muse, mutect2, varscan2
- HECW2 | c.4173G>C p.G1391= | Silent (SNP) | VAF 30/434 reads (7%) | called by muse, mutect2
- HFM1 | c.609A>T p.S203= | Silent (SNP) | VAF 16/434 reads (4%) | called by muse, mutect2
- HIRIP3 | c.204C>T p.S68= | Silent (SNP) | VAF 13/380 reads (3%) | catalogued as rs1201699924; called by muse, mutect2
- HMGXB3 | c.3981C>T p.A1327= (on ENST00000613459; = p.A1081= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/636 reads (7%) | called by muse, mutect2
- IFNA5 | c.348G>A p.L116= | Silent (SNP) | VAF 20/418 reads (5%) | called by muse, mutect2
- IGKV1D-8 | c.168C>A p.A56= | Silent (SNP) | VAF 45/726 reads (6%) | called by muse, mutect2
- IREB2 | c.1890C>G p.P630= | Silent (SNP) | VAF 24/470 reads (5%) | called by muse, mutect2
- IRX1 | c.264C>A p.L88= | Silent (SNP) | VAF 11/133 reads (8%) | called by muse, mutect2
- KIF26A | c.3196C>T p.L1066= | Silent (SNP) | VAF 33/321 reads (10%) | called by muse, mutect2, varscan2
- KRTAP5-11 | c.276C>T p.C92= | Silent (SNP) | VAF 38/950 reads (4%) | called by muse, mutect2
- LAP3 | c.84C>T p.S28= | Silent (SNP) | VAF 20/414 reads (5%) | called by muse, mutect2
- LIN7B | c.63C>T p.L21= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as rs1447580686, COSV99674359; called by muse, mutect2
- LMNB2 | c.951C>T p.L317= | Silent (SNP) | VAF 31/250 reads (12%) | catalogued as rs1378654583; called by muse, mutect2, varscan2
- LRRC9 | c.2889T>C p.N963= | Silent (SNP) | VAF 28/252 reads (11%) | called by muse, mutect2, varscan2
- MAGEC3 | c.678C>T p.F226= | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- MANSC1 | c.1005G>A p.V335= | Silent (SNP) | VAF 72/545 reads (13%) | called by muse, mutect2, varscan2
- MAP3K3 | c.810C>G p.V270= | Silent (SNP) | VAF 26/593 reads (4%) | called by muse, mutect2
- MCOLN3 | c.126C>G p.L42= | Silent (SNP) | VAF 16/510 reads (3%) | catalogued as COSV62014353; called by muse, mutect2
- METTL25 | c.153C>G p.V51= | Silent (SNP) | VAF 54/709 reads (8%) | called by muse, mutect2
- MON1B | c.1605G>C p.T535= | Silent (SNP) | VAF 30/568 reads (5%) | called by muse, mutect2
- MORC1 | c.2436A>T p.T812= | Silent (SNP) | VAF 67/491 reads (14%) | catalogued as rs114538315; called by muse, mutect2, varscan2
- MROH2A | c.129C>A p.I43= | Silent (SNP) | VAF 34/335 reads (10%) | called by muse, mutect2, varscan2
- MROH9 | c.1687C>T p.L563= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as rs1396618074; called by muse, mutect2, varscan2
- MSTN | c.576G>A p.L192= | Silent (SNP) | VAF 51/460 reads (11%) | catalogued as rs763988846; called by muse, mutect2, varscan2
- MTUS2 | c.3831C>A p.I1277= (on ENST00000612955 / NM_001366650.1; = p.I256= on NM_015233.6) | Silent (SNP) | VAF 15/363 reads (4%) | catalogued as COSV66420750; called by muse, mutect2
- MYH2 | c.4293C>G p.V1431= | Silent (SNP) | VAF 36/497 reads (7%) | catalogued as COSV55447420; called by muse, mutect2
- MYH3 | c.2295C>T p.F765= | Silent (SNP) | VAF 38/1024 reads (4%) | called by muse, mutect2
- NCF2 | c.105C>A p.P35= | Silent (SNP) | VAF 64/457 reads (14%) | called by muse, mutect2, varscan2
- NLRX1 | c.1803C>A p.I601= | Silent (SNP) | VAF 25/214 reads (12%) | called by muse, mutect2, varscan2
- OR10J3 | c.750C>T p.I250= | Silent (SNP) | VAF 102/694 reads (15%) | called by muse, mutect2, varscan2
- PAX5 | c.111C>A p.V37= | Silent (SNP) | VAF 40/556 reads (7%) | called by muse, mutect2
- PCDHA9 | c.2112C>T p.I704= | Silent (SNP) | VAF 22/734 reads (3%) | catalogued as COSV65325426, COSV65332501; called by muse, mutect2
- PIEZO2 | c.129G>A p.L43= | Silent (SNP) | VAF 20/382 reads (5%) | called by muse, mutect2
- PLEKHG6 | c.1542G>A p.L514= | Silent (SNP) | VAF 21/682 reads (3%) | called by muse, mutect2
- PRORP | c.1128G>A p.V376= | Silent (SNP) | VAF 42/800 reads (5%) | catalogued as rs1419618384, COSV51618448; called by muse, mutect2
- PTPRQ | c.6804G>A p.L2268= (on ENST00000616559; = p.L2235= on NM_001145026.2) | Silent (SNP) | VAF 11/277 reads (4%) | called by muse, mutect2
- PXDNL | c.3243C>T p.F1081= | Silent (SNP) | VAF 82/821 reads (10%) | catalogued as COSV62487530; called by muse, mutect2, varscan2
- RAI2 | c.1332A>G p.E444= | Silent (SNP) | VAF 38/327 reads (12%) | called by muse, mutect2, varscan2
- RPL13 | c.588A>G p.A196= | Silent (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- RPP25 | c.549G>T p.A183= | Silent (SNP) | VAF 20/495 reads (4%) | catalogued as rs1485108833; called by muse, mutect2
- RPS15 | c.21G>A p.K7= | Silent (SNP) | VAF 30/659 reads (5%) | called by muse, mutect2
- RYR1 | c.9426C>G p.T3142= | Silent (SNP) | VAF 57/361 reads (16%) | called by muse, mutect2, varscan2
- RYR2 | c.6202C>A p.R2068= | Silent (SNP) | VAF 11/172 reads (6%) | catalogued as COSV63666342; called by muse, mutect2
- RYR2 | c.6483C>T p.L2161= | Silent (SNP) | VAF 75/847 reads (9%) | catalogued as rs1351039185, COSV100772198, COSV63677904, COSV63679071; called by muse, mutect2
- SELE | c.1705C>T p.L569= | Silent (SNP) | VAF 24/678 reads (4%) | called by muse, mutect2
- SIDT1 | c.1083C>A p.A361= | Silent (SNP) | VAF 49/574 reads (9%) | catalogued as COSV53498252; called by muse, mutect2
- SIGLEC5 | c.1413G>A p.G471= | Silent (SNP) | VAF 52/576 reads (9%) | catalogued as COSV55784135; called by muse, mutect2
- SLC5A5 | c.57C>G p.V19= | Silent (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- SLC6A15 | c.138G>A p.E46= | Silent (SNP) | VAF 24/844 reads (3%) | called by muse, mutect2
- SLC6A18 | c.1200T>A p.P400= | Silent (SNP) | VAF 25/440 reads (6%) | called by muse, mutect2
- SLCO1B3 | c.816T>C p.S272= | Silent (SNP) | VAF 34/591 reads (6%) | called by muse, mutect2
- SNRNP40 | c.117G>A p.A39= | Silent (SNP) | VAF 12/272 reads (4%) | catalogued as COSV99745503; called by muse, mutect2
- SOAT1 | c.1056C>T p.I352= | Silent (SNP) | VAF 33/746 reads (4%) | called by muse, mutect2
- SPTA1 | c.5841G>A p.K1947= | Silent (SNP) | VAF 46/1072 reads (4%) | catalogued as COSV100934620; called by muse, mutect2
- SRSF7 | c.141A>T p.P47= | Silent (SNP) | VAF 32/539 reads (6%) | called by muse, mutect2
- STAB2 | c.4212G>T p.G1404= | Silent (SNP) | VAF 39/580 reads (7%) | called by muse, mutect2
- SYT3 | c.1305C>T p.L435= | Silent (SNP) | VAF 51/419 reads (12%) | called by muse, mutect2, varscan2
- TAT | c.195G>C p.V65= | Silent (SNP) | VAF 32/715 reads (4%) | catalogued as COSV100587512; called by muse, mutect2
- TBC1D1 | c.3111G>A p.Q1037= | Silent (SNP) | VAF 16/310 reads (5%) | called by muse, mutect2
- TBX5 | c.267G>C p.V89= | Silent (SNP) | VAF 44/860 reads (5%) | called by muse, mutect2
- TMCO5A | c.171C>T p.G57= | Silent (SNP) | VAF 28/563 reads (5%) | catalogued as COSV100148764; called by muse, mutect2
- TMEM132C | c.2199C>T p.F733= | Silent (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- TMEM63C | c.471C>T p.I157= | Silent (SNP) | VAF 18/412 reads (4%) | called by muse, mutect2
- TRIM51GP | c.495C>T p.I165= | Silent (SNP) | VAF 43/355 reads (12%) | called by muse, mutect2, varscan2
- UNCX | c.816C>A p.P272= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as rs768743283; called by muse, mutect2, varscan2
- USH2A | c.14199C>A p.A4733= | Silent (SNP) | VAF 16/520 reads (3%) | called by muse, mutect2
- UTRN | c.8721C>T p.V2907= | Silent (SNP) | VAF 44/516 reads (9%) | called by muse, mutect2
- VWC2 | c.225C>T p.D75= | Silent (SNP) | VAF 29/234 reads (12%) | called by muse, mutect2, varscan2
- WDR70 | c.60G>A p.Q20= | Silent (SNP) | VAF 24/638 reads (4%) | called by muse, mutect2
- WFS1 | c.1545C>T p.F515= | Silent (SNP) | VAF 36/972 reads (4%) | catalogued as rs1315205050; called by muse, mutect2
- ZNF143 | c.1029C>T p.I343= | Silent (SNP) | VAF 40/699 reads (6%) | catalogued as COSV55178624; called by muse, mutect2
- ZNF175 | c.414G>A p.L138= | Silent (SNP) | VAF 38/567 reads (7%) | catalogued as rs767406872; called by muse, mutect2
- ABCD1 | c.1081+63G>A | Intron (SNP) | VAF 21/198 reads (11%) | called by muse, mutect2, varscan2
- ADAM3A | n.1961C>T | RNA (SNP) | VAF 15/190 reads (8%) | called by muse, mutect2
- ADAMTSL4 | c.-85+1036C>T | Intron (SNP) | VAF 71/925 reads (8%) | catalogued as COSV54998592; called by muse, mutect2
- ASH1L | chr1:155563321 C>T | 5'Flank (SNP) | VAF 15/130 reads (12%) | called by muse, mutect2, varscan2
- AZGP1P1 | n.164C>T | RNA (SNP) | VAF 53/650 reads (8%) | called by muse, mutect2
- CABP4 | c.367-10C>T | Intron (SNP) | VAF 20/552 reads (4%) | catalogued as rs1414687784, COSV100351641; called by muse, mutect2
- CCDC9B | c.874+52A>T | Intron (SNP) | VAF 28/413 reads (7%) | called by muse, mutect2
- CCL7 | c.*51T>A | 3'UTR (SNP) | VAF 39/396 reads (10%) | catalogued as rs199823422; called by muse, mutect2
- CENPP | c.-12C>T | 5'UTR (SNP) | VAF 38/464 reads (8%) | catalogued as rs781297566; called by muse, mutect2
- CEP112 | c.2394+25470C>A | Intron (SNP) | VAF 32/414 reads (8%) | called by muse, mutect2
- CHRNA4 | c.*2442C>T | 3'UTR (SNP) | VAF 36/522 reads (7%) | called by muse, mutect2
- CHRNA4 | c.*2441C>G | 3'UTR (SNP) | VAF 36/536 reads (7%) | called by muse, mutect2
- COLEC11 | c.-26-675T>A | Intron (SNP) | VAF 37/396 reads (9%) | called by muse, mutect2
- CREBL2 | c.-18G>A | 5'UTR (SNP) | VAF 28/474 reads (6%) | called by muse, mutect2
- DAW1 | c.973+5097C>G | Intron (SNP) | VAF 24/472 reads (5%) | called by muse, mutect2
- ELP6 | c.*4G>A | 3'UTR (SNP) | VAF 32/544 reads (6%) | called by muse, mutect2
- ETNK1 | c.156+262G>T | Intron (SNP) | VAF 36/466 reads (8%) | catalogued as rs1227946171; called by muse, mutect2
- FAM214A | c.-31A>T | 5'UTR (SNP) | VAF 32/583 reads (5%) | called by muse, mutect2
- FAM53A | c.883-2684A>T | Intron (SNP) | VAF 20/432 reads (5%) | called by muse, mutect2
- FANCD2 | chr3:10101203 G>A | 3'Flank (SNP) | VAF 64/758 reads (8%) | catalogued as rs755911397; called by muse, mutect2
- FOXP2 | c.-210G>A | 5'UTR (SNP) | VAF 25/710 reads (4%) | called by muse, mutect2
- FSHB | c.*11A>T | 3'UTR (SNP) | VAF 41/623 reads (7%) | called by muse, mutect2
- GALK1 | c.-1C>G | 5'UTR (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2
- GALNT13 | c.1531-4538G>T | Intron (SNP) | VAF 33/450 reads (7%) | called by muse, mutect2
- GATM | c.70-394G>A | Intron (SNP) | VAF 28/708 reads (4%) | called by muse, mutect2
- IGFN1 | c.1242-1617G>A | Intron (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- IP6K2 | c.-131+1746C>T | Intron (SNP) | VAF 94/812 reads (12%) | called by muse, mutect2, varscan2
- ITPR2 | c.5554+248C>T | Intron (SNP) | VAF 50/964 reads (5%) | called by muse, mutect2
- KCTD1 | c.-15-46432G>T | Intron (SNP) | VAF 28/492 reads (6%) | called by muse, mutect2
- LINC02551 | n.1306G>C | RNA (SNP) | VAF 22/626 reads (4%) | catalogued as rs1018653806; called by muse, mutect2
- MMAB | c.*2830A>T | 3'UTR (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- MPRIP | c.2163+2896G>T | Intron (SNP) | VAF 48/873 reads (5%) | called by muse, mutect2
- MPV17 | c.70+23A>G | Intron (SNP) | VAF 31/758 reads (4%) | called by muse, mutect2
- MYADML | n.517G>A | RNA (SNP) | VAF 17/109 reads (16%) | called by muse, mutect2, varscan2
- NT5C1B | c.1071+172C>T | Intron (SNP) | VAF 62/796 reads (8%) | called by muse, mutect2
- NTF3 | c.-27G>T | 5'UTR (SNP) | VAF 42/549 reads (8%) | called by muse, mutect2
- OPRM1 | c.1165-11079T>C | Intron (SNP) | VAF 43/572 reads (8%) | called by muse, mutect2
- OR2L1P | n.666T>C | RNA (SNP) | VAF 60/461 reads (13%) | called by muse, mutect2, varscan2
- PCCA | c.1900-23747G>A | Intron (SNP) | VAF 28/518 reads (5%) | called by muse, mutect2
- PPME1 | c.645-9C>G | Intron (SNP) | VAF 20/488 reads (4%) | called by muse, mutect2
- PREB | c.*12C>T | 3'UTR (SNP) | VAF 32/400 reads (8%) | catalogued as rs1462172253; called by muse, mutect2
- PTENP1 | n.960C>T | RNA (SNP) | VAF 77/930 reads (8%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34158906 C>A | 5'Flank (SNP) | VAF 27/318 reads (8%) | called by muse, mutect2
- SAMM50 | c.-24G>A | 5'UTR (SNP) | VAF 61/530 reads (12%) | catalogued as COSV63110255; called by muse, mutect2, varscan2
- SDCBP2 | c.225+92C>G | Intron (SNP) | VAF 32/401 reads (8%) | called by muse, mutect2
- SEC14L1 | c.2042+33G>T | Intron (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- SH3BP2 | c.1549-9C>T | Intron (SNP) | VAF 39/698 reads (6%) | catalogued as rs1435336450; called by muse, mutect2
- SLC4A3 | c.812-621G>A | Intron (SNP) | VAF 15/312 reads (5%) | called by muse, mutect2
- SPATA18 | c.1479+46C>T | Intron (SNP) | VAF 46/610 reads (8%) | catalogued as rs373306077; called by muse, mutect2
- SRPK3 | chrX:153780401 G>A | 5'Flank (SNP) | VAF 62/329 reads (19%) | called by muse, mutect2, varscan2
- SYT14 | chr1:210163180 G>A | 3'Flank (SNP) | VAF 26/362 reads (7%) | called by muse, mutect2
- TAZ | c.*423C>T | 3'UTR (SNP) | VAF 28/342 reads (8%) | called by muse, mutect2
- TBX2 | chr17:61412291 G>A | 3'Flank (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- TMEM33 | c.-83del | 5'UTR (DEL) | VAF 40/398 reads (10%) | called by mutect2, varscan2
- TPO | c.2748+107C>T | Intron (SNP) | VAF 28/575 reads (5%) | catalogued as rs370368246, COSV61101067; called by muse, mutect2
- UBE2D3 | c.-15G>C | 5'UTR (SNP) | VAF 26/667 reads (4%) | called by muse, mutect2
- VPS11 | c.-371C>G | 5'UTR (SNP) | VAF 14/343 reads (4%) | called by muse, mutect2
- YIPF3 | c.82-18G>A | Intron (SNP) | VAF 26/512 reads (5%) | called by muse, mutect2
- ZAN | c.7787+61C>T | Intron (SNP) | VAF 10/95 reads (11%) | called by mutect2, varscan2
- ZNF7 | c.-41C>G | 5'UTR (SNP) | VAF 16/324 reads (5%) | catalogued as COSV100296112; called by muse, mutect2
- ZNF778 | c.*5233C>G | 3'UTR (SNP) | VAF 56/1646 reads (3%) | called by muse, mutect2
- ZNF780A | chr19:40072963 G>A | 3'Flank (SNP) | VAF 14/198 reads (7%) | catalogued as rs1465712225; called by muse, mutect2
